Surgical pathology report (de-identified scan), TCGA case TCGA-85-A4CL, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-A4CL-01A (Primary Tumor).

Gross Description: Lung with peribronchial tumor of 3 ? 2 cm in its size, grey-whitish coloured.

Microscopic Description: 1) Squamous cell carcinoma (poorly differentiated), G3;

2) Node in the S6 - hondroma (hondromatous hamartoma);

3) Bifurcational lymph node demonstrate anthracosis;

4) Three bronchopulmonary lymph nodes demonstrate signs sinus. histiocytosis.

Diagnosis Details: Tumor Features: Unknown, Tumor Extent: Localized, NOS, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: LUNG TISSUE CHECKLIST

Specimen type: Pneumonectomy

Tumor site: Lung

Tumor size: 2 x 0 x 3 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Not specified

Other tumor nodules: Not specified

Lymph nodes: 0/4 positive for metastasis (Bifurcational, bronchopulmonary 0/4)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Right- lower

ICD-0-3
carcinoma, squamous cell, NOS
(R) 8070/3
Site: lung, lower lobe C34.3

hw
9/24/12

hw 9/3/12

Source: NCI Genomic Data Commons file 1ea485d4-08f7-43fb-a10a-868462768d3d (TCGA-85-A4CL.85FD4E7E-5365-4217-84FA-758275B18C93.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).